Somatic mutation profile of tumor specimen TCGA-AB-2937-03A (aliquot TCGA-AB-2937-03A-01W-0732-08) from TCGA case TCGA-AB-2937, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.0 years (13,149 days).
Specimen TCGA-AB-2937-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca58911d-0011-44d2-94e3-5924042de6b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2937-11A (Solid Tissue Normal), aliquot TCGA-AB-2937-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb60cedb-7ef7-419d-8733-c494eb62279d

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSTK1 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV64423971, COSV64424272; called by muse, mutect2, varscan2
- OTX2 | c.106dup p.R36Pfs*52 (on ENST00000408990 / NM_172337.3; = p.R44Pfs*52 on NM_021728.4) | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | catalogued as rs758119168; called by mutect2, pindel, varscan2
- SPRED2 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs901352433; called by muse, mutect2
- TMTC4 | c.1720C>T p.R574W (on ENST00000376234 / NM_001350577.2; = p.R593W on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs750836771, COSV60891349; called by muse, mutect2, varscan2
- HNRNPK | c.213+1delinsTAGA p.X71_splice | Splice Site (INS) | VAF 22/116 reads (19%) | called by pindel, varscan2*
